Somatic mutation profile of tumor specimen TCGA-DJ-A3VA-01A (aliquot TCGA-DJ-A3VA-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.7 years (14,495 days).
Specimen TCGA-DJ-A3VA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4393e1f5-4d4b-4133-b48a-83b3a2d3dae5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VA-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VA-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b669fc7-cfa7-4300-8c61-eba1a5fab38e

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NUFIP1 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV64791633; called by muse, mutect2
- SEMA3B | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV60351950; called by muse, mutect2, varscan2
- TACC2 | c.3763G>T p.A1255S | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.159); catalogued as COSV57763296; called by muse, mutect2, varscan2
- TTN | c.1322C>A p.P441Q | Missense Mutation (SNP) | VAF 23/272 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV60189911; called by muse, mutect2
- WDR88 | c.1245C>T p.C415= | Splice Region (SNP) | VAF 67/213 reads (31%) | catalogued as rs753214293, COSV63450700; called by muse, mutect2, varscan2
- PDCL2 | c.561C>A p.L187= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV55261634; called by muse, mutect2, varscan2
- PPP3R2 | c.504C>G p.L168= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV62456083; called by muse, mutect2
- TAX1BP1 | c.2040A>T p.R680= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV55294980; called by muse, mutect2, varscan2
